Surgical pathology report (de-identified scan), TCGA case TCGA-FD-A5BS, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - University Of Chicago, specimen TCGA-FD-A5BS-01A (Primary Tumor).

[page 1 of 3]
ICD-O-3

Carcinoma, Urothelial NOS
8120/3

Gender: Male

Race: Unknown

Path Site: Bladder, lateral and
Posterior Wall C67.8

Pathology Report:

CSCF Site: Bladder, posterior Wall
C67.4

Surgical Pathology Report

QW 12/24/12

FINAL PATHOLOGIC DIAGNOSIS

- A. Bladder, prostate, seminal vesicles and vasa deferentia;
cystoprostatectomy:
- Invasive high-grade urothelial carcinoma consistent with
lymphoepithelioma-like carcinoma (see parameters below).
- Prostatic adenocarcinoma (see parameters below).
- Bladder diverticulum.
- B. Right pelvic lymph nodes; dissection:
- No carcinoma in fifteen lymph nodes (0/15).
- C. Left pelvic lymph nodes; dissection:
- No carcinoma in eight lymph nodes (0/8).

Urothelial Carcinoma Pathologic Parameters 8120/3

1. Tumor type: Lymphoepithelioma-like carcinoma
2. Grade of tumor: High-grade
3. Depth of invasion: Perivesicular adipose
4. Tumor distribution: Solitary, 4.5 cm in greatest dimension involving left lateral wall and posterior wall
5. Ureteral margins: Negative
6. Distal urethral margin: Negative
7. Soft tissue margin or serosa: Negative
8. Lymphovascular invasion: Absent
8. Lymph nodes: No carcinoma in twenty-three lymph nodes (0/23)
9. pTNM: T3b, N0, MX

Effective this Checklist utilizes the 7th edition TNM staging system for Bladder of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

Radical Prostatectomy Pathologic Parameters

1. Gleason Score: 3+3
2. Perineural Invasion: Absent
3. Tumor Location: Peripheral zone - Right
4. Tumor Volume Estimate: 1%
5. High-grade P.I.N.: Absent
6. Seminal Vesicles: Negative for tumor
7. Extraprostatic extension: Absent
8. Peripheral Margin: Negative for tumor
9. Distal (apical) Margin: Negative for tumor
10. Proximal (basilar) Margin: Negative for tumor
11. Regional Lymph Nodes (right and left): Negative for tumor
12. pTNM: pT2a N0

Effective this Checklist utilizes the 7th edition TNM staging system for prostatectomy of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

xx
[] M.D.

[page 2 of 3]
Interpretation performed by the Attending Pathologist and reviewed with the Resident/Fellow, [], M.D.
Electronically Signed Out by [], M.D.

Clinical History:

The patient is a -year-old male with high-grade bladder cancer with lymphoepithelioma-like features undergoing cystoprostatectomy was neobladder.

Specimens Received:

A: Bladder, prostate, seminal vesicles and vasa deferentia
B: Right pelvic lymph nodes
C: Left pelvic lymph nodes

Gross Description:

The specimens are received in three containers each labeled with the patient's name and medical record number.

A. The first container is additionally identified as, "prostate, bladder". Received fresh is a 20 x 10.5 x 4.5 cm cystoprostatectomy specimen consisting of a 11 x 8 x 3 cm bladder with attached mesenteric fat and a 5.5 x 3.5 x 3.5 cm prostate. The right seminal vesicles measure 3.5 x 2 x 0.7 cm and right vas deferens measures 14.5 x 0.3 x 0.8 cm. The left seminal vesicles measures 1.7 x 1.6 x 0.9 cm and left vas deferens measures 3.5 cm. Both seminal vesicles were received disrupted. The right ureteral stump measures 0.7 cm, the left measures 2.5 cm, and both demonstrate intact, patent lumens this diameter ranging from 0.4-0.5 cm. The urethral margin was submitted for intraoperative diagnosis and read by Dr. [] as "urethral margin, negative for tumor". The remnant of frozen specimen is submitted in cassette A1 FS.

The right half of the prostate and bladder is inked blue and the left half is inked black. The bladder and prostate are opened anteriorly along the urethra. Apex and lateral aspects of prostate are disrupted and sutured back together. The prostate is surrounded by a thin, intact membranous capsule and sectioning demonstrates rubbery, pink-tan, peri-urethral nodularity with bright yellow irregularly-shaped areas scattered in periureteral area and peripheral zone and ranging in size from 0.1-0.5 cm in greatest dimension.

The opened bladder reveals a 4.5 x 3.5 cm area of shaggy, hemorrhagic mucosal ulceration located in left posterolateral wall. On cut section, the mass extends into perivesical fat and is 0.4 cm from the deep margin. The ulcerated area is 1.7 cm from the left ureter orifice and more than 5 cm from the distal urethral margin. Adjacent to the ulcerated area is a 3.7 x 2.4 x 2.0 cm diverticulum located in the posterior wall and extending to the dome. Bladder wall in the area of diverticula ranges from 0.2-0.4 cm. Gross photographs are taken. The surrounding bladder mucosa is edematous, red-pink with variable wall thickness ranging from 0.4-1.0 cm. Bilateral ureteral orifices, adjacent to the trigone, are identified and probe patent. There are two separate detached blood vessels measuring 2.3 and 7.5 cm in length and 0.4 cm in diameter. The perivesical fat is dissected and no apparent lymph nodes are identified. Representative sections are submitted as follows:

A2: Right ureter resection margin
A3: Left ureter resection margin
A4: Distal prostatic urethral margin (apex)
A5-A10: Bladder mass/ulceration
A11: Bladder diverticulum
A12: Uninvolved bladder mucosa bladder dome
A13: Uninvolved bladder mucosa anterior wall
A14: Uninvolved bladder mucosa posterior wall
A15-A17: Representative right lobe of prostate from apex to base, seminal vesicles
A18-A20: Representative left lobe of prostate submitted from apex to base, seminal vesicles

[page 3 of 3]
B. The second container is additionally identified as, "right pelvic lymph nodes". Received fresh and placed in formalin is an aggregate of fibroadipose tissue measuring 5.8 x 5.2 x 2.2 cm. The tissue is dissected to reveal several apparent lymph nodes ranging in size from 0.5-1.9 cm. Block summary:

B1: One bisected lymph node
B2: One bisected lymph node
B3: 2 lymph nodes
B4: 3 lymph nodes
B5: 3 lymph nodes
B6: 5 lymph node candidates

C. The third container is additionally identified as, "left pelvic nodes". Received fresh and placed in formalin is an aggregate of fibroadipose tissue measuring 6.0 x 4.7 x 2.3 cm. The tissue is bisected to reveal several apparent lymph nodes ranging in size from 0.3-3.8 cm. Some lymph nodes are matted and firm. Block summary:

C1-C2: One sectioned lymph node
C3-C4: One sectioned lymph node in each cassette
C5: 3 lymph nodes
C6: 6 lymph node candidates

xxxx
[], MD, PhD

Dual/Synchronous Primary Notes	prostate ✓	

Source: NCI Genomic Data Commons file 62d3c939-43d4-4084-b2d4-ba3c7b40eeeb (TCGA-FD-A5BS.09B55176-4149-4D38-B5D9-F3F98DDA02C3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).